Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5510, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5510-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] In addition, he has an elevated serum PSA level of 15.3 ng/ml. A previous prostate needle biopsy performed [REDACTED] reveals bilateral prostatic adenocarcinoma (3+3=6 in the left, 3+4 = 7 in the right).

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy and bilateral pelvic lymph node dissection.

CGA-EJ-5510

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, EXCISION -

FIVE (5) BENIGN LYMPH NODES (0/5). NO EVIDENCE OF MALIGNANCY.

PART 2: LEFT PELVIC LYMPH NODES, EXCISION -

TWELVE (12) BENIGN LYMPH NODES (0/12). NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, SEMINAL VESICLES, AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 4+3=7, INVOLVING BOTH RIGHT AND LEFT LOBES OF THE PROSTATE GLAND (SLIDES 3Y-3DD, 3JJ, 3NN, 3PP). GLEASON PATTERN 4 COMPONENT COMPRISES 50-60% OF THE SAMPLED TUMOR VOLUME.
- B. MAXIMAL TUMOR DIAMETER IS 2.0 CM IN A HISTOLOGIC SECTION (SLIDE 3DD).
- C. CARCINOMA COMPRISES 10-15% OF THE SAMPLED PROSTATE GLAND VOLUME.
- D. MULTIFOCAL CARCINOMATOUS PERINEURAL INVASION IS IDENTIFIED (SLIDES 3Z-3DD).
- E. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. BENIGN SEMINAL VESICLES AND DISTAL VASA DEFERENTIA.
- G. ALL SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- H. FOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.
- I. TNM PATHOLOGIC STAGE: T2c, N0, MX.
- J. HISTOLOGIC GRADE: G3-4.
- K. NON-NEOPLASTIC PROSTATE WITH NODULAR HYPERPLASIA AND FOCAL GLANDULAR ATROPHY (See Synoptic).

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 15.3
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	52.61gm
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - 1 or 2 foci away from tumor
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	17
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 133c34d1-25ea-4298-a9ea-00b3baac5e93 (TCGA-EJ-5510.9F549743-CBB3-46BB-9356-40F80E961B4D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).